Somatic mutation profile of tumor specimen RC-B6S6-TTP1-A (aliquot RC-B6S6-TTP1-A-1-1-D-A94K-47) from RC case RC-B6S6, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 69.3 years (25,303 days).
Specimen RC-B6S6-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12928286-f15c-4097-8bd9-cd2d5375213f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6S6-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6S6-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e046d58-92b5-4007-8230-0036382b92fa

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Intron 7, Nonsense Mutation 6, Frame Shift Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR1 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as CM087499; called by muse, mutect2
- AP5Z1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | catalogued as rs767325342, COSV100804143; called by muse, mutect2, varscan2
- BDP1 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs767188313; called by muse, mutect2
- BRINP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66513568; called by muse, mutect2
- CAPN9 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1159311293; called by muse, mutect2
- CNNM2 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV63996394; called by muse, mutect2
- CNTNAP1 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as rs199782327; called by muse, mutect2, varscan2
- DCAF8L2 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as rs1319121489; called by muse, mutect2
- DIAPH2 | c.3194C>A p.S1065* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | catalogued as COSV61270947; called by muse, mutect2
- EZH2 | c.2060C>T p.A687V (on ENST00000460911 / NM_001203247.2; = p.A692V on NM_004456.5) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57452636; called by muse, mutect2
- FRAS1 | c.7515C>A p.F2505L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV99349848; called by muse, mutect2
- IGLV11-55 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as COSV101135393; called by muse, varscan2
- KRT20 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1480882219; called by muse, mutect2
- MYH3 | c.3868C>T p.R1290C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1352788534; called by muse, mutect2, varscan2
- NR0B2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs746783997, COSV54259892; called by muse, mutect2
- OR8K1 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.404); catalogued as rs770988066; called by muse, mutect2
- POM121L12 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs755281512, COSV101374925, COSV68693180; called by muse, mutect2
- PRR36 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); catalogued as rs1177010553; called by muse, mutect2, varscan2
- REV3L | c.6350A>G p.Y2117C | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV62619845; called by muse, mutect2
- RNASE9 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs748283218, COSV58880408; called by muse, mutect2
- SEL1L3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1309384902; called by muse, mutect2
- SEZ6L | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230779974; called by muse, mutect2
- TAP1 | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 27/333 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV100841214; called by muse, mutect2
- TBX22 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423305487; called by muse, mutect2
- TF | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748119838, COSV53917789; called by muse, mutect2
- TMEM245 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1363291970; called by muse, mutect2, varscan2
- UGT2B10 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55320864; called by muse, mutect2
- ALG11 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2
- ANKRD36B | c.49A>C p.K17Q | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.403); called by muse, mutect2
- ARHGEF19 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CLK4 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2
- CPSF7 | c.487C>T p.Q163* (on ENST00000394888 / NM_001136040.4; = p.Q206* on NM_024811.4) | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2
- CYTH1 | c.644T>G p.I215S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- GDF7 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- H4C11 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); called by muse, mutect2
- HUWE1 | c.9563G>T p.C3188F | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- IGKV2-30 | c.332A>T p.Y111F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- IGLV4-60 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- INPP5D | c.2528T>C p.L843S (on ENST00000445964 / NM_001017915.3; = p.L842S on NM_005541.5) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2
- KALRN | c.6066T>A p.C2022* (on ENST00000360013 / NM_001024660.4; = p.C325* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- MMP8 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MOSMO | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- MYO7B | c.1892G>T p.S631I | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2
- NEK8 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- NPY5R | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.913); called by muse, mutect2
- NWD2 | c.2945T>C p.V982A | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- NYX | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- OR11H6 | c.650G>C p.C217S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2
- PCDHGA3 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 35/460 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLVAP | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- PRICKLE1 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RELB | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- RYR2 | c.13539C>G p.I4513M | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TENM4 | c.3813C>A p.F1271L | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- TMED6 | c.200A>T p.Y67F | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.063); called by muse, mutect2
- TNFRSF14 | c.174_178del p.S58Rfs*17 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- XPO1 | c.1483A>T p.N495Y | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XPO1 | c.1482G>T p.L494F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB11 | c.1801T>C p.L601= | Splice Region (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- ZNF544 | c.1831A>C p.K611Q | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- AACS | c.2013C>A p.G671= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- ADCY9 | c.1896G>A p.S632= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as rs564832517, COSV53573869; called by muse, mutect2
- ASPM | c.1680C>T p.N560= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as rs751204699, COSV54136887; called by muse, mutect2
- CRPPA | c.1212A>G p.R404= (on ENST00000407010 / NM_001368197.1; = p.R354= on NM_001101417.4) | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- DAB1 | c.1116C>T p.I372= (on ENST00000371231; = p.I339= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 36/227 reads (16%) | catalogued as rs1049719265, COSV64690645, COSV64697021; called by muse, mutect2, varscan2
- DGKK | c.459G>A p.P153= | Silent (SNP) | VAF 20/408 reads (5%) | called by muse, mutect2
- MYPN | c.3717A>T p.S1239= | Silent (SNP) | VAF 7/175 reads (4%) | called by muse, mutect2
- NIBAN1 | c.2499C>T p.T833= | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as rs529680480; called by muse, mutect2
- PERP | c.480G>A p.T160= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs139581829; called by muse, mutect2
- PFKL | c.693C>T p.P231= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs199922371, COSV100827039; called by muse, mutect2
- PRKCH | c.144C>T p.S48= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV100273676; called by muse, mutect2
- SLC15A4 | c.1488T>A p.S496= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- TEPSIN | c.606G>A p.Q202= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- ZBTB38 | c.2487A>G p.T829= | Silent (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- HHAT | c.1245+70G>A | Intron (SNP) | VAF 13/145 reads (9%) | catalogued as rs1048313942; called by muse, mutect2
- IGFN1 | c.1242-2885G>A | Intron (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- MARCHF1 | c.242+1037T>C | Intron (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- MARCHF1 | c.242+760T>A | Intron (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- MXD4 | c.195-2703G>A | Intron (SNP) | VAF 6/87 reads (7%) | catalogued as rs1424777606; called by muse, mutect2
- RAB11FIP5 | c.1569-4400G>A | Intron (SNP) | VAF 20/236 reads (8%) | catalogued as rs962142497; called by muse, mutect2
- ZIC4 | c.-15-1184A>C | Intron (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
